Gene-level copy-number profile of tumor specimen TARGET-10-PANURW-09A from TARGET case TARGET-10-PANURW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,598 days).
Specimen TARGET-10-PANURW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.b51b9698-d619-5fd8-83b3-9a7d522eb03b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PANURW-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/7394fbc2-bc63-43f5-9645-a3b7f620b8db

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 445; copy number 2: 5,170; copy number 3: 3,426; copy number 4: 50,202; copy number 5: 862; copy number 6: 30; copy number 7: 87; copy number 9: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,322,031–36,335,406, 2 genes: EVA1B, AL591845.1.
- chr1:247,416,156–247,449,108, 1 gene (within-gene range 0–4): NLRP3.
- chr2:174,431,571–174,487,094, 1 gene (within-gene range 0–4): GPR155.
- chr7:38,257,879–38,340,998, 14 genes (within-gene range 0–4): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.
- chr7:142,265,833–142,313,666, 7 genes: TRY2P, AC245088.1, PRSS3P3, TRBV1, TRBV2, TRBV3-1, TRBV4-1.
- chr8:51,996,210–52,008,355, 1 gene (within-gene range 0–3): AC064807.3.
- chr9:107,663,140–107,663,246, 1 gene: RNU6-996P.
- chr10:55,667,341–55,668,350, 1 gene: GAPDHP21.
- chr11:97,000,274–97,000,711, 1 gene: MED28P5.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr13:83,298,071–83,298,167, 1 gene: RNU6-67P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,360,024–116,370,090, 1 gene, copy number 9: LSAMP-AS1.
- chr19:58,083,838–58,118,427, 1 gene, copy number 10: ZSCAN18.

Autosomal genes at a single copy (total copy number 1): 79. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
